Somatic mutation profile of tumor specimen TCGA-EJ-A6RC-01A (aliquot TCGA-EJ-A6RC-01A-11D-A32B-08) from TCGA case TCGA-EJ-A6RC, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.6 years (23,598 days).
Specimen TCGA-EJ-A6RC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6839549-370d-4d51-b912-fa7365e93316.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A6RC-10A (Blood Derived Normal), aliquot TCGA-EJ-A6RC-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a42fa631-161a-45d1-ada4-51a57d192363

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACE | c.2495C>T p.P832L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as rs761838241, COSV99327936; called by muse, mutect2, varscan2
- ATF7IP | c.2260C>T p.P754S | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.698); catalogued as COSV99662331; called by muse, mutect2, varscan2
- C1orf127 | c.940G>T p.V314F | Missense Mutation (SNP) | VAF 4/77 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100983527; called by muse, mutect2
- CEP162 | c.1357A>G p.T453A | Missense Mutation (SNP) | VAF 4/77 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100003556; called by muse, mutect2
- JMJD1C | c.7237C>T p.Q2413* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | catalogued as COSV100550923; called by muse, mutect2
- KCNE3 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.037); catalogued as COSV100035708; called by muse, mutect2
- MORN4 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs181071367, COSV56731202; called by muse, mutect2
- NXPE3 | c.302C>G p.T101S | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56292355, COSV99840260; called by muse, mutect2
- PPFIA4 | c.473T>A p.F158Y | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99830668; called by muse, mutect2
- SALL1 | c.2440G>A p.D814N | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.728); catalogued as COSV99177087, COSV99192141; called by muse, mutect2
- TEX264 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.55); catalogued as COSV100392798; called by muse, mutect2, varscan2
- CSMD1 | c.2151G>A p.G717= (on ENST00000520002; = p.G716= on NM_033225.6) | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as rs1233751836, COSV100155132, COSV59293782; called by muse, mutect2
- MYOC | c.1014C>T p.G338= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs750946621, COSV50676162; called by muse, mutect2, varscan2
- OSBPL2 | c.630C>T p.S210= (on ENST00000313733 / NM_144498.4; = p.S198= on NM_014835.4) | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as rs1197350779, COSV100569376; called by muse, mutect2
- SUGP2 | c.2110C>T p.L704= | Silent (SNP) | VAF 4/82 reads (5%) | catalogued as COSV100432486; called by muse, mutect2
